Somatic mutation profile of tumor specimen TCGA-TQ-A7RM-01A (aliquot TCGA-TQ-A7RM-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RM, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 41.5 years (15,154 days).
Specimen TCGA-TQ-A7RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d9b8a8c-607d-469f-820f-0a55676b1912.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RM-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RM-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fa038e2-84d5-44f8-8942-252d90af4870

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 11, Nonsense Mutation 2, 3'UTR 1, Splice Region 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 76/159 reads (48%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 127/133 reads (95%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ARHGAP44 | c.2311T>G p.S771A | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.931); catalogued as COSV99310202; called by muse, mutect2
- BICDL1 | c.1052G>A p.S351N | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99985762; called by muse, mutect2, varscan2
- BRWD3 | c.4702C>T p.R1568W | Missense Mutation (SNP) | VAF 77/165 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs748635655, COSV100955730; called by muse, mutect2, varscan2
- C2orf16 | c.5468G>A p.R1823H | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs753664844, COSV62674078; called by muse, mutect2, varscan2
- CAPRIN2 | c.1268G>T p.W423L | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV51831284, COSV99195433; called by muse, mutect2, varscan2
- CHRDL1 | c.640G>T p.G214* (on ENST00000372045; = p.G220* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 55/242 reads (23%) | catalogued as COSV99487767; called by muse, mutect2, varscan2
- CLCN5 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs782817681, CM165162, COSV100259860; ClinVar: benign; called by muse, mutect2, varscan2
- DENND3 | c.785C>T p.T262M | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754541615, COSV99370447; called by muse, mutect2, varscan2
- DOCK9 | c.2748C>T p.Y916= (on ENST00000376460 / NM_001366676.2; = p.Y917= on NM_015296.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 22/59 reads (37%) | catalogued as rs779438223, COSV59624175; called by muse, mutect2, varscan2
- ENOX2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100583862; called by muse, mutect2, varscan2
- EPX | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 43/380 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs191966823, COSV99836296; called by muse, mutect2, varscan2
- FAM209B | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.654); catalogued as COSV100990929, COSV100990967; called by muse, mutect2, varscan2
- FAM50B | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as rs1365145844, COSV100976517; called by muse, mutect2
- FBXO42 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 77/161 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as rs1467463636, COSV100981668, COSV100981877; called by muse, mutect2, varscan2
- GABRB1 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 82/391 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV99780476; called by muse, mutect2, varscan2
- GFI1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758869486, COSV54042918, COSV99647424; called by muse, mutect2, varscan2
- GJA1 | c.1025A>G p.Q342R | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV99246848; called by muse, mutect2, varscan2
- GRIN2A | c.1508A>C p.Q503P | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100408608; called by muse, mutect2, varscan2
- HHIPL2 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100596651; called by muse, mutect2
- HOOK3 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100295118, COSV100295873; called by muse, mutect2
- HS6ST3 | c.1268A>G p.K423R | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100940096; called by muse, mutect2, varscan2
- KIF2C | c.1175A>G p.K392R | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV100945620; called by muse, mutect2, varscan2
- KLF9 | c.732G>C p.L244F | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV101009524; called by muse, mutect2, varscan2
- KRT86 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs764200311, COSV99524876; called by muse, varscan2
- LIFR | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs200967700, COSV99663455; called by muse, mutect2, varscan2
- LRP6 | c.4148C>T p.T1383I | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.033); catalogued as COSV99742607; called by muse, mutect2, varscan2
- LRRC75B | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV99958626; called by muse, mutect2, varscan2
- LTF | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773253706, COSV99207067; called by muse, mutect2, varscan2
- MAP4 | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 139/292 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99274814; called by muse, mutect2, varscan2
- MYH8 | c.3697G>T p.D1233Y | Missense Mutation (SNP) | VAF 91/340 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101238288; called by muse, mutect2, varscan2
- MYO18A | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs1403127997, COSV100571978; called by muse, mutect2
- NXPE4 | c.1598G>A p.G533E (on ENST00000375478 / NM_001077639.2; = p.G249E on NM_017678.3) | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV100970321; called by muse, mutect2, varscan2
- OR1N1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.345); catalogued as rs944986995, COSV100509654; called by muse, mutect2, varscan2
- OR2G2 | c.812G>A p.R271K | Missense Mutation (SNP) | VAF 225/376 reads (60%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100189615, COSV100189837, COSV100189876; called by muse, mutect2, varscan2
- OR8B3 | c.446A>T p.Y149F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as COSV100660368; called by muse, mutect2, varscan2
- PABPC5 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 6/143 reads (4%) | SIFT tolerated (0.94); PolyPhen benign (0.065); catalogued as COSV57040474; called by muse, mutect2
- PDE2A | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as rs768257356, COSV100557694; called by muse, mutect2, varscan2
- PIP5K1B | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs1385672588, COSV99598140; called by muse, mutect2, varscan2
- PLA2R1 | c.1678T>A p.F560I | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99322335; called by muse, mutect2, varscan2
- RRM2B | c.723C>G p.Y241* | Nonsense Mutation (SNP) | VAF 35/250 reads (14%) | catalogued as COSV99309932; called by muse, mutect2, varscan2
- SLC9A7 | c.670T>C p.F224L | Missense Mutation (SNP) | VAF 87/193 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as COSV100091622; called by muse, mutect2, varscan2
- SMPD1 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as COSV100192426; called by muse, mutect2, varscan2
- SV2B | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs201612018, COSV57701832; called by muse, mutect2, varscan2
- TAX1BP1 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99604195; called by muse, mutect2, varscan2
- ULBP3 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 65/284 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.255); catalogued as COSV100949592; called by muse, mutect2, varscan2
- UVSSA | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770306039, COSV66229813; called by muse, mutect2, varscan2
- ZC3H12B | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.997); catalogued as rs764558199, COSV59049132; called by muse, mutect2, varscan2
- ZNF423 | c.599A>G p.K200R (on ENST00000563137 / NM_001379286.1; = p.K192R on NM_015069.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.955); catalogued as COSV99280255; called by muse, mutect2, varscan2
- ZNF561 | c.778A>G p.K260E | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV57178012; called by muse, mutect2, varscan2
- ZW10 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 89/406 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV99562488; called by muse, mutect2, varscan2
- MALT1 | c.599del p.F200Sfs*39 | Frame Shift Del (DEL) | VAF 21/117 reads (18%) | called by mutect2, pindel, varscan2
- ARAP2 | c.1758T>C p.V586= | Silent (SNP) | VAF 59/231 reads (26%) | catalogued as COSV100394228; called by muse, mutect2, varscan2
- C8B | c.1617G>A p.R539= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100980676; called by muse, varscan2
- CXCL6 | c.168G>A p.L56= | Silent (SNP) | VAF 76/83 reads (92%) | catalogued as rs1302505879, COSV99884844; called by muse, mutect2, varscan2
- FLNC | c.2109G>A p.K703= | Silent (SNP) | VAF 33/290 reads (11%) | catalogued as COSV100367698; called by muse, mutect2, varscan2
- LCE1C | c.171G>A p.G57= | Silent (SNP) | VAF 87/174 reads (50%) | catalogued as rs753370924, COSV100908415; called by muse, mutect2, varscan2
- LRP1 | c.5625C>T p.A1875= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as rs766786921, COSV99674765; called by muse, mutect2, varscan2
- NLRC3 | c.474C>T p.F158= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs547058160, COSV57090947, COSV57091002; called by muse, mutect2, varscan2
- OTUD7B | c.1260C>T p.V420= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV100967389; called by muse, mutect2, varscan2
- RS1 | c.540G>A p.S180= | Silent (SNP) | VAF 47/205 reads (23%) | catalogued as rs767660711, COSV101183723; called by muse, mutect2, varscan2
- SLCO4C1 | c.1944T>C p.N648= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as COSV100194602; called by muse, mutect2, varscan2
- ZNF676 | c.645C>A p.T215= (on ENST00000650058; = p.T183= on NM_001001411.3) | Silent (SNP) | VAF 24/177 reads (14%) | called by muse, mutect2, varscan2
- GABRA3 | c.-26-29883C>T | Intron (SNP) | VAF 17/100 reads (17%) | catalogued as COSV100942462; called by muse, mutect2, varscan2
- VNN3 | c.*410C>A | 3'UTR (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99258059; called by muse, mutect2, varscan2
